Somatic mutation profile of tumor specimen MP2PRT-PATAHM-TMP1-A (aliquot MP2PRT-PATAHM-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATAHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,737 days).
Specimen MP2PRT-PATAHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a74701f-f9c4-420b-bda5-1e98a091b15a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATAHM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATAHM-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48d1da32-a46a-4d7f-99f6-baccb76fe7f4

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 66/371 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 133/428 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by mutect2, varscan2
- PTCH1 | c.3886G>A p.G1296R | Missense Mutation (SNP) | VAF 141/895 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.616); catalogued as rs372828014, COSV59464956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1306881491; called by muse, mutect2, varscan2
- SOS1 | c.848_849insC p.E284* | Frame Shift Ins (INS) | VAF 29/191 reads (15%) | called by mutect2, varscan2
- VWA3A | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- FANCA | c.3753C>T p.C1251= | Silent (SNP) | VAF 104/286 reads (36%) | catalogued as rs752126515; called by muse, mutect2, varscan2
- NLRP2 | c.2388C>T p.T796= | Silent (SNP) | VAF 180/521 reads (35%) | catalogued as rs761014781; called by muse, mutect2, varscan2
- SYNE1 | c.6762G>T p.L2254= (on ENST00000367255 / NM_182961.4; = p.L2261= on NM_033071.3) | Silent (SNP) | VAF 19/271 reads (7%) | called by muse, mutect2
- TSPO2 | c.405G>A p.L135= | Silent (SNP) | VAF 167/712 reads (23%) | called by muse, mutect2, varscan2
